CCDI case PBCJAB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f9e8372e-5914-4ac2-97b3-f193cf5c5c6f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.7 years (6,821 days).

Biospecimens (3 samples)
- Sample 0DTB84: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTB91: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
